Somatic mutation profile of tumor specimen TCGA-06-0875-01A (aliquot TCGA-06-0875-01A-01W-0424-08) from TCGA case TCGA-06-0875, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.1 years (22,312 days).
Specimen TCGA-06-0875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a000ddde-b333-49d5-91da-0a593dbb57b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0875-10A (Blood Derived Normal), aliquot TCGA-06-0875-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eb430a9-c5ba-43f4-86fa-ff4db1241c85

The open-access MAF lists 85 somatic variants for this specimen: 74 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 40, Frame Shift Ins 28, Silent 11, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3507+1G>A p.X1169_splice (on ENST00000265723 / NM_018849.3; = p.X1162_splice on NM_000443.4) | Splice Site (SNP) | VAF 92/868 reads (11%) | catalogued as rs764513998, COSV55941506; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 32/190 reads (17%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 106/839 reads (13%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 393/528 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 90/121 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGRN | c.2873G>A p.G958D | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.456); catalogued as COSV65069928; called by muse, mutect2, varscan2
- AKAP13 | c.7075C>G p.R2359G (on ENST00000394518 / NM_007200.5; = p.R2363G on NM_006738.6) | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778806648, COSV63460084; called by muse, mutect2, varscan2
- AMPH | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 83/404 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167299845, COSV57743752; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs758492903; called by mutect2, varscan2
- ASB11 | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV60355403; called by muse, mutect2, varscan2
- BSN | c.10022C>T p.P3341L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56527039; called by muse, mutect2, varscan2
- C12orf4 | c.284T>G p.L95* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as COSV54207423; called by muse, mutect2, varscan2
- CCN6 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 251/766 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV57889467; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | catalogued as rs760923345; called by mutect2, varscan2
- CDKL1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53579882; called by muse, mutect2, varscan2
- CELSR3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs144228630; called by muse, mutect2, varscan2
- CFAP65 | c.1896dup p.M633Hfs*35 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | catalogued as rs762731091; called by mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 39/350 reads (11%) | catalogued as rs747299117; called by mutect2, varscan2
- CIDEA | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs149949331; called by muse, mutect2, varscan2
- CLDN18 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs772493450, COSV59302428, COSV59302939; called by muse, mutect2, varscan2
- CYP3A43 | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV55936427; called by muse, mutect2, varscan2
- FAM83E | c.889dup p.Q297Pfs*33 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs773971919; called by mutect2, varscan2
- FLG | c.4649C>G p.S1550* | Nonsense Mutation (SNP) | VAF 115/276 reads (42%) | catalogued as COSV64242625; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | catalogued as rs752538869; called by mutect2, varscan2
- GPR141 | c.74T>A p.F25Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV57733996; called by muse, mutect2, varscan2
- GPR146 | c.263dup p.S89Efs*348 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs757419572; called by mutect2, pindel, varscan2
- GRPR | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867462308, COSV66669550; called by muse, mutect2, varscan2
- IDO1 | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.564); catalogued as COSV53716307; called by muse, mutect2, varscan2
- IL12B | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs771683283, COSV51455193; called by muse, mutect2, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 78/682 reads (11%) | catalogued as rs745545309; called by mutect2, varscan2
- KANK1 | c.2717C>G p.T906S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV63212618; called by muse, mutect2, varscan2
- KARS1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs761886340, COSV56694369; called by mutect2, varscan2
- KDM1B | c.1697C>T p.A566V (on ENST00000449850; = p.A334V on NM_153042.4) | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV52811335; called by muse, mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs750932259; called by mutect2, varscan2
- LRRC55 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201169874; called by muse, mutect2, varscan2
- LRRC8C | c.1524dup p.W509Lfs*20 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | catalogued as rs762972819; called by mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 24/182 reads (13%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPK8IP1 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 248/626 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1409806572, COSV53797057; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 18/96 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MDGA2 | c.2415T>C p.S805= (on ENST00000399232 / NM_001113498.2; = p.S507= on NM_182830.4) | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62114705; called by muse, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | catalogued as rs772983071; called by mutect2, varscan2
- MED13 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV67265894; called by muse, mutect2
- MRGPRX2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs753275049, COSV61674269; called by muse, mutect2, varscan2
- MUC16 | c.35227G>A p.V11743M | Missense Mutation (SNP) | VAF 138/277 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.192); catalogued as rs551319234, COSV67480130; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 16/132 reads (12%) | catalogued as rs761123152; called by mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 24/208 reads (12%) | catalogued as rs772347389; called by mutect2, varscan2
- NIPA1 | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV61680009; called by muse, mutect2, varscan2
- NIPAL2 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs145862248; called by muse, mutect2, varscan2
- NME8 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs144650767; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 38/153 reads (25%) | catalogued as rs754860965; called by mutect2, varscan2
- NUCB1 | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as COSV54388192; called by muse, mutect2
- PAGE2B | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66611364; called by muse, mutect2, varscan2
- PANK4 | c.72dup p.D25Rfs*50 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | catalogued as rs768596064; called by mutect2, pindel
- PRSS35 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as rs773975931, COSV63800668; called by muse, mutect2, varscan2
- PTEN | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV64289872, COSV64299283; called by muse, mutect2, varscan2
- RFT1 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV56249114; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 61/276 reads (22%) | catalogued as rs745519558; called by mutect2, varscan2
- RUSC2 | c.3747G>T p.E1249D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV63428830; called by muse, mutect2, varscan2
- SAMD9L | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV59085115; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 47/218 reads (22%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC16A6 | c.1247A>C p.E416A | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs1555748272, COSV59177632; called by muse, mutect2, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | catalogued as rs748701652; called by mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs746816975; called by mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TGFBR2 | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM064335, COSV55450870; called by muse, mutect2, varscan2
- TMC1 | c.814A>T p.R272W | Missense Mutation (SNP) | VAF 149/215 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs111839361, COSV52776648; called by muse, mutect2, varscan2
- TRPM8 | c.2301dup p.E768Rfs*14 | Frame Shift Ins (INS) | VAF 15/140 reads (11%) | catalogued as rs770879940; called by mutect2, varscan2
- ZDHHC5 | c.1040dup p.T348Dfs*13 | Frame Shift Ins (INS) | VAF 18/168 reads (11%) | catalogued as rs750782730; called by mutect2, pindel
- ZFPL1 | c.320dup p.T108Nfs*32 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs1217305091; called by pindel, varscan2
- CIT | c.5165A>T p.Y1722F | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- COL16A1 | c.746dup p.E250Rfs*13 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- H3C12 | c.120_123del p.R41Tfs*49 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- TG | c.7984T>C p.F2662L | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AK7 | c.1845C>T p.D615= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as rs199616462, COSV50882050; called by muse, mutect2, varscan2
- CD163 | c.123C>A p.T41= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs769294403; called by muse, mutect2, varscan2
- CHGB | c.1422C>T p.Y474= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs774814252, COSV66760714; called by muse, mutect2, varscan2
- COG4 | c.270G>C p.L90= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV60423056, COSV60423326; called by muse, mutect2, varscan2
- DNAH5 | c.11664C>T p.Y3888= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as rs754874486, COSV54229389, COSV54236409; called by muse, mutect2, varscan2
- FTHL17 | c.183C>T p.D61= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs1183198016, COSV63266432, COSV63267272; called by muse, mutect2, varscan2
- NAT16 | c.321G>A p.L107= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs760126152, COSV55864764; called by muse, mutect2, varscan2
- SLC13A2 | c.117G>A p.A39= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs181965873, COSV58995291; called by muse, mutect2, varscan2
- TFPI2 | c.288C>T p.C96= | Silent (SNP) | VAF 50/531 reads (9%) | catalogued as COSV55991852; called by muse, mutect2
- WSCD1 | c.435C>T p.Y145= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV58495852; called by muse, mutect2, varscan2
- ZNF264 | c.522G>A p.E174= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs754446379, COSV54042147; called by muse, mutect2, varscan2
